Somatic mutation profile of tumor specimen TCGA-VS-A9UH-01A (aliquot TCGA-VS-A9UH-01A-11D-A42O-09) from TCGA case TCGA-VS-A9UH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 53.3 years (19,454 days).
Specimen TCGA-VS-A9UH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea66f12f-7c4b-4bf6-b63e-ad433c103368.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9UH-10A (Blood Derived Normal), aliquot TCGA-VS-A9UH-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/530795a7-5bc9-41cb-b102-d0729b9474cf

The open-access MAF lists 213 somatic variants for this specimen: 163 protein-altering or splice-affecting, 47 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 47, Nonsense Mutation 15, Splice Site 2, Splice Region 1, RNA 1, In Frame Del 1, 5'UTR 1, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NAGLU | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894597, CM981365, COSV99864121; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.2519G>C p.R840P | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.413); catalogued as COSV55750016, COSV99933491; called by muse, mutect2, varscan2
- ABCA13 | c.11071C>G p.L3691V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101446949, COSV71284322; called by muse, mutect2, varscan2
- ABCA5 | c.3623C>T p.S1208L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101201134; called by muse, mutect2, varscan2
- AC008397.2 | c.1957C>A p.P653T | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as COSV99441669; called by muse, mutect2
- ACTA2 | c.800C>G p.S267C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.244); catalogued as COSV99827086; called by muse, mutect2, varscan2
- ADAMTS8 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.067); catalogued as COSV99960914; called by muse, mutect2, varscan2
- ALDH3B2 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs149110344; called by muse, mutect2, varscan2
- ANK2 | c.8185G>A p.E2729K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.053); catalogued as COSV100001561, COSV100003077; called by muse, varscan2
- APLP2 | c.1096C>G p.P366A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as COSV99599693; called by muse, mutect2, varscan2
- ARHGEF2 | c.217G>C p.V73L (on ENST00000361247 / NM_001162383.2; = p.V46L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV100560557; called by muse, mutect2
- ASAP1 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV100727255; called by muse, mutect2, varscan2
- ATAD2 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV99784668; called by muse, mutect2, varscan2
- ATP1A3 | c.2439C>G p.I813M (on ENST00000545399 / NM_001256214.2; = p.I800M on NM_152296.5) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100132243, COSV57490679; called by muse, mutect2, varscan2
- ATP2C1 | c.2047C>G p.Q683E | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100146677; called by muse, mutect2
- ATP6AP2 | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as rs375148460, COSV101011490; called by muse, mutect2, varscan2
- ATP8A2 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99681865; called by muse, mutect2, varscan2
- BAIAP2L2 | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs764609892, COSV100140422; called by muse, mutect2, varscan2
- BAZ1B | c.2455G>C p.D819H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.204); catalogued as COSV59993605; called by muse, mutect2, varscan2
- BAZ1B | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as COSV100289758; called by muse, varscan2
- BAZ1B | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as COSV100289761; called by muse, varscan2
- BHLHE41 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs944617151, COSV99658280; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.262C>G p.P88A | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs764054526, COSV57280608; called by muse, mutect2, varscan2
- BMPR2 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV101001483; called by muse, mutect2, varscan2
- BRCA2 | c.6004G>A p.E2002K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.108); catalogued as COSV101204213; called by muse, mutect2, varscan2
- BRCA2 | c.6343G>A p.E2115K | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.228); catalogued as COSV101204214; called by muse, mutect2, varscan2
- BRF1 | c.1485G>C p.E495D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.737); catalogued as COSV100527307; called by muse, mutect2, varscan2
- C12orf56 | c.1262G>A p.R421K (on ENST00000543942 / NM_001170633.2; = p.R261K on NM_001099676.3) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100399403; called by muse, mutect2, varscan2
- C9orf131 | c.2617C>T p.Q873* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100398096; called by muse, mutect2, varscan2
- CAMTA2 | c.921C>G p.I307M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.862); catalogued as COSV100772596; called by muse, mutect2, varscan2
- CCDC60 | c.1044G>C p.E348D | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100555069; called by muse, mutect2, varscan2
- CCNQ | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as COSV52345461; called by muse, mutect2, varscan2
- CFAP20 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as rs1161083546, COSV99343474; called by muse, mutect2, varscan2
- CFAP206 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 33/171 reads (19%) | catalogued as COSV51537854, COSV99739511; called by muse, mutect2, varscan2
- CHAF1A | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.013); catalogued as COSV100011141; called by muse, mutect2, varscan2
- CRTAM | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV57071353, COSV99911986; called by muse, mutect2, varscan2
- CSMD3 | c.5561C>T p.S1854L (on ENST00000297405 / NM_001363185.1; = p.S1750L on NM_052900.3) | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV52169723, COSV99833841; called by muse, mutect2, varscan2
- CYP4V2 | c.1539C>G p.I513M | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV66507607; called by muse, mutect2, varscan2
- DAAM1 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.588); catalogued as rs746938240, COSV100658384; called by muse, mutect2, varscan2
- DHDDS | c.926G>T p.R309L (on ENST00000236342 / NM_001319959.1; = p.R310L on NM_024887.3) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99360441; called by muse, mutect2, varscan2
- DNAH2 | c.4744G>A p.E1582K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.716); catalogued as COSV101209292; called by muse, mutect2, varscan2
- DPP8 | c.527G>A p.G176E (on ENST00000341861 / NM_001320875.2; = p.G160E on NM_017743.6) | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100202348; called by muse, mutect2
- EDRF1 | c.3107G>A p.S1036N (on ENST00000356792 / NM_001202438.2; = p.S1002N on NM_015608.2) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.154); catalogued as COSV100523464; called by muse, mutect2, varscan2
- EIF4G3 | c.3319C>G p.P1107A | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99944226; called by muse, mutect2
- ELOA2 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV99795827, COSV99796566; called by muse, varscan2
- EPPK1 | c.6562A>C p.S2188R | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.054); catalogued as COSV101599835; called by muse, mutect2
- FBXO16 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100672298; called by muse, mutect2, varscan2
- FGF6 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs746392824, COSV99960240; called by muse, mutect2, varscan2
- FLG | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.543); catalogued as COSV100911557, COSV64243248; called by muse, mutect2, varscan2
- FOXK1 | c.1073C>G p.S358C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100195124; called by muse, mutect2, varscan2
- FRY | c.7112C>G p.S2371* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100969243; called by muse, mutect2, varscan2
- FZD9 | c.1685G>A p.G562E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.844); catalogued as COSV100289697, COSV100289753; called by muse, mutect2, varscan2
- GFOD2 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.017); catalogued as COSV99263543; called by muse, mutect2, varscan2
- GLYATL2 | c.491C>G p.S164* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as rs1418355370, COSV54851458, COSV99780368; called by mutect2, varscan2
- GOLGA4 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs960502792, COSV100728881; called by muse, mutect2, varscan2
- GPCPD1 | c.1717C>G p.Q573E | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100980174; called by muse, mutect2, varscan2
- GPR21 | c.701G>A p.S234N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV101016442; called by muse, mutect2, varscan2
- HDLBP | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV100190560; called by muse, mutect2, varscan2
- HECW2 | c.3427G>C p.E1143Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99647108; called by mutect2, varscan2
- HIRIP3 | c.106C>G p.H36D | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV99662878, COSV99663040; called by muse, mutect2, varscan2
- HMGXB4 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV99330096; called by mutect2, varscan2
- HOXB2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100344644, COSV57486258; called by muse, mutect2, varscan2
- HSD3B2 | c.446C>G p.T149R | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as COSV101027475; called by muse, mutect2
- HSPA6 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100554136; called by muse, mutect2, varscan2
- HTR2C | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99349288; called by muse, mutect2, varscan2
- HUWE1 | c.3624G>C p.K1208N | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99472237; called by muse, mutect2, varscan2
- IFT81 | c.1050C>G p.I350M | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54365551; called by muse, mutect2, varscan2
- IGFBP5 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV99288929; called by muse, mutect2, varscan2
- IGSF11 | c.481G>C p.V161L (on ENST00000393775 / NM_001015887.3; = p.V160L on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV100677307, COSV61174668, COSV61176145; called by muse, mutect2
- INO80 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV99054981; called by muse, mutect2, varscan2
- IQCA1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as COSV99609473; called by muse, mutect2, varscan2
- IQSEC3 | c.3302T>C p.V1101A | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV58290168; called by muse, mutect2, varscan2
- IQUB | c.1855T>A p.S619T | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV100227087; called by muse, mutect2, varscan2
- KCNA4 | c.1367A>G p.K456R | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100068933; called by muse, mutect2
- KIF19 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as rs765352519, COSV63428883; called by muse, mutect2, varscan2
- KMT2C | c.3343C>T p.Q1115* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | catalogued as rs1422672826, COSV100071664; called by muse, varscan2
- KMT2D | c.4051G>T p.E1351* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99981490; called by muse, mutect2, varscan2
- KRTAP5-2 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 7/83 reads (8%) | catalogued as rs758065516, COSV101295081; called by muse, mutect2
- LMTK2 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV51996571, COSV99806815; called by muse, mutect2
- LRP2 | c.8602G>C p.E2868Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV99788362; called by muse, mutect2, varscan2
- LRPPRC | c.2167C>T p.R723* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as rs1022152551, COSV53242772; called by muse, mutect2, varscan2
- LRRC2 | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as COSV99947415; called by mutect2, varscan2
- MAN2A1 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.151); catalogued as COSV99811037; called by muse, mutect2, varscan2
- MGAT5 | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs746885077, COSV56101642, COSV99924463; called by muse, mutect2, varscan2
- MSC | c.546C>G p.F182L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100335689; called by muse, mutect2, varscan2
- MUC17 | c.6376C>G p.P2126A | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100073132; called by muse, varscan2
- MYCBP2 | c.12302G>A p.G4101E (on ENST00000357337; = p.G4139E on NM_015057.5) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.182); catalogued as COSV100630305; called by mutect2, varscan2
- NFE2L3 | c.1605G>C p.L535F | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs148491307, COSV99283701; called by muse, mutect2, varscan2
- NLRP5 | c.3550G>C p.D1184H | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as COSV101173666; called by muse, mutect2
- NOBOX | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV99779424; called by muse, mutect2, varscan2
- NOTCH3 | c.1978G>C p.E660Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99657157; called by muse, mutect2, varscan2
- NPHP1 | c.2038G>A p.E680K (on ENST00000393272 / NM_207181.4; = p.E681K on NM_000272.5) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100338056, COSV57210482; called by muse, mutect2, varscan2
- NSG2 | c.143C>A p.T48K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100292811; called by muse, mutect2, varscan2
- OR13H1 | c.926G>C p.*309Sext*10 | Nonstop Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100088252; called by muse, mutect2, varscan2
- OR51F2 | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100438034, COSV59064918; called by muse, mutect2, varscan2
- PACRGL | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV54842961; called by mutect2, varscan2
- PAPSS1 | c.1102A>G p.M368V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.561); catalogued as COSV99492044; called by muse, mutect2
- PBX4 | c.706C>A p.P236T | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs778805645, COSV52060541; called by muse, mutect2, varscan2
- PCSK1 | c.1475G>A p.R492K | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100227094; called by muse, mutect2, varscan2
- PDGFA | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.793); catalogued as COSV100627314; called by muse, mutect2, varscan2
- PHPT1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); catalogued as COSV99915627; called by muse, mutect2, varscan2
- PIBF1 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV100411479; called by muse, mutect2, varscan2
- PIGR | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.22); catalogued as rs1228076614, COSV62904093; called by muse, mutect2
- PIK3R1 | c.1670G>C p.R557P (on ENST00000521381 / NM_181523.3; = p.R287P on NM_181504.4) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57131637, COSV57133365, COSV99143544; called by muse, mutect2, varscan2
- PIWIL2 | c.2455G>C p.D819H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100769394; called by muse, mutect2, varscan2
- PLEKHH3 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as rs137859811, COSV99257916; called by muse, mutect2, varscan2
- PLXNB2 | c.5305G>A p.D1769N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100834046; called by muse, mutect2, varscan2
- PML | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV51442565, COSV99167077; called by muse, mutect2, varscan2
- PNPT1 | c.1535G>C p.G512A | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99569989; called by muse, mutect2, varscan2
- POM121C | c.1573A>G p.N525D (on ENST00000607367; = p.N283D on NM_001099415.3) | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV99992692; called by muse, mutect2
- PPP2R5A | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99806631; called by muse, mutect2, varscan2
- PROSER3 | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.617); catalogued as COSV99994550; called by muse, mutect2, varscan2
- PSMD11 | c.978G>T p.L326F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV99912462; called by muse, mutect2, varscan2
- PTCHD1 | c.2587G>C p.E863Q | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.221); catalogued as COSV101037641; called by muse, mutect2, varscan2
- RB1 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as CM022830, COSV57322209, COSV57324774, COSV99924697; called by muse, mutect2, varscan2
- RB1 | c.1943C>G p.S648* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as CD116047, COSV57294571; called by muse, mutect2, varscan2
- REPS1 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.471); catalogued as COSV99238681; called by muse, mutect2, varscan2
- RHBDD1 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as rs1430043349, COSV100391791; called by muse, mutect2, varscan2
- RNF213 | c.12433G>A p.D4145N | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV100300538; called by muse, mutect2, varscan2
- RSPH3 | c.457C>T p.R153W (on ENST00000252655; = p.R11W on NM_031924.8) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as rs1364048040, COSV99396322; called by muse, mutect2, varscan2
- SEC13 | c.318G>A p.V106= (on ENST00000350697 / NM_183352.3; = p.V109= on NM_030673.4) | Splice Region (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100491372; called by muse, varscan2
- SERBP1 | c.901C>T p.R301W (on ENST00000370995 / NM_001018067.2; = p.R280W on NM_015640.4) | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV100769100; called by muse, mutect2
- SERINC3 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99667715; called by muse, mutect2, varscan2
- SKA3 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100006344, COSV53435469; called by muse, mutect2
- SLC22A2 | c.885G>C p.K295N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV100870982; called by muse, mutect2, varscan2
- SLC26A4 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as COSV99706942; called by muse, mutect2, varscan2
- SLC41A3 | c.1106-1G>C p.X369_splice | Splice Site (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100259594; called by muse, mutect2
- SLFN12 | c.1247C>G p.S416C | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.669); catalogued as COSV100513079; called by muse, mutect2, varscan2
- SOS2 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV99366057; called by mutect2, varscan2
- SOX21 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100977917; called by muse, mutect2
- SPINK13 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV101268298, COSV68241995; called by muse, mutect2, varscan2
- STX2 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV99892840; called by muse, mutect2, varscan2
- SYCP2 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100698244; called by muse, mutect2, varscan2
- SYNE1 | c.23098C>G p.L7700V (on ENST00000367255 / NM_182961.4; = p.L7629V on NM_033071.3) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV55065776, COSV99563452; called by muse, mutect2, varscan2
- SYNE1 | c.21034G>A p.E7012K (on ENST00000367255 / NM_182961.4; = p.E6941K on NM_033071.3) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99563457; called by muse, mutect2, varscan2
- TANC2 | c.3052G>A p.E1018K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV101267413; called by muse, mutect2, varscan2
- TAPBP | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV101444947; called by mutect2, varscan2
- THRAP3 | c.854C>G p.S285* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100663367; called by muse, mutect2, varscan2
- TMC2 | c.345G>T p.K115N | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100727583; called by muse, mutect2, varscan2
- TMEM62 | c.1081C>T p.H361Y | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1461183163, COSV99543593; called by muse, varscan2
- TNIK | c.3112G>C p.E1038Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV99457156; called by muse, mutect2, varscan2
- TNKS2 | c.2428C>G p.Q810E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.044); catalogued as rs767450342, COSV100861082; called by muse, mutect2, varscan2
- TNPO1 | c.2563G>C p.D855H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as COSV61520690; called by muse, mutect2, varscan2
- TRIM55 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs747495074, COSV99396778; called by muse, mutect2, varscan2
- TRIM7 | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as COSV99220195; called by muse, mutect2, varscan2
- TTC12 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as COSV59101268; called by muse, mutect2, varscan2
- TUT7 | c.3818C>G p.S1273* | Nonsense Mutation (SNP) | VAF 28/148 reads (19%) | catalogued as COSV99462990; called by muse, mutect2, varscan2
- TXK | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51919776, COSV99972424; called by muse, mutect2, varscan2
- UBAP1 | c.1267-1G>C p.X423_splice | Splice Site (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99903164; called by muse, mutect2
- UGT1A7 | c.233C>G p.S78* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV60850052; called by muse, mutect2, varscan2
- USH2A | c.11828G>A p.R3943K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as rs1297122035, COSV100234399; called by muse, mutect2, varscan2
- USP45 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.938); catalogued as rs1335560680, COSV100569647; called by muse, mutect2, varscan2
- VCX | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV58232922; called by muse, mutect2, varscan2
- WSCD1 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV100496561; called by muse, mutect2, varscan2
- ZCCHC17 | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV100703989; called by muse, mutect2
- ZNF304 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs762038911, COSV56585868; called by muse, mutect2, varscan2
- AATF | c.908C>T p.T303I | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- ABCA1 | c.3887C>G p.S1296C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); called by muse, mutect2
- ACTB | c.148_150del p.K50del | In Frame Del (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- RBP3 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- STAT5B | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYNRG | c.973C>G p.L325V | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRAJ14 | c.18C>G p.I6M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- ADAM22 | c.729G>C p.L243= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV55990179; called by muse, mutect2, varscan2
- ARAP3 | c.150C>T p.S50= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs372589227, COSV53352076; called by muse, mutect2, varscan2
- ARHGDIG | c.162G>A p.K54= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99548790; called by mutect2, varscan2
- BTBD11 | c.1065C>G p.V355= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99775671; called by muse, mutect2, varscan2
- CCDC144A | c.474G>A p.L158= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as COSV100138529; called by muse, mutect2, varscan2
- CHRND | c.636G>A p.E212= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99285782; called by muse, varscan2
- CHST7 | c.528C>T p.D176= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs921002483, COSV52100848, COSV99332931; called by muse, mutect2, varscan2
- DENND4C | c.5871C>G p.L1957= (on ENST00000434457 / NM_001330640.2; = p.L1908= on NM_017925.7) | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100194484; called by muse, mutect2, varscan2
- ELL | c.735C>T p.L245= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs372970180; called by muse, mutect2, varscan2
- ERCC6L | c.2338C>T p.L780= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV100559106; called by muse, mutect2, varscan2
- FAM227B | c.160C>T p.L54= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV100174993; called by muse, mutect2, varscan2
- FBXL8 | c.204C>G p.L68= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99263510; called by muse, mutect2, varscan2
- FGD1 | c.453G>A p.L151= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV100911054; called by muse, mutect2, varscan2
- FHOD1 | c.787C>T p.L263= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV99264103; called by muse, mutect2
- FLT1 | c.2625G>A p.L875= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs772980978, COSV99156075; called by mutect2, varscan2
- GEMIN5 | c.939C>G p.L313= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV99593868; called by muse, mutect2, varscan2
- GSDME | c.1014C>G p.L338= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100742329; called by muse, mutect2, varscan2
- HPRT1 | c.147T>G p.L49= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100053190; called by muse, mutect2
- HPS3 | c.1473G>A p.V491= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV56055594; called by muse, mutect2, varscan2
- INTU | c.702G>A p.V234= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99611656; called by muse, varscan2
- KIF16B | c.1818T>A p.L606= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100734265; called by muse, mutect2, varscan2
- LMLN | c.1758C>G p.G586= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV100218551; called by muse, mutect2, varscan2
- LYPD1 | c.267C>G p.S89= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100257706; called by mutect2, varscan2
- MYO15A | c.8511C>T p.F2837= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99232666; called by muse, mutect2, varscan2
- NPY1R | c.789C>T p.I263= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs865784759, COSV99648733; called by muse, mutect2, varscan2
- OR51F2 | c.12C>G p.L4= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100438030; called by muse, mutect2
- OR9Q1 | c.912C>G p.L304= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100109940, COSV100110368; called by muse, mutect2, varscan2
- PRLHR | c.525C>A p.L175= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV53303110, COSV53305574; called by muse, mutect2, varscan2
- PRPF8 | c.5583C>T p.I1861= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs780838844, COSV100517481; called by muse, mutect2, varscan2
- RALGAPA2 | c.1833C>G p.L611= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV99173583; called by muse, mutect2, varscan2
- RCBTB1 | c.705G>C p.V235= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs772585122, COSV99319503; called by muse, mutect2, varscan2
- RELN | c.6630G>A p.L2210= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100633668; called by muse, mutect2, varscan2
- RNF17 | c.4407G>A p.K1469= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV99693136; called by muse, mutect2, varscan2
- SALL1 | c.3438G>C p.S1146= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99173809; called by muse, mutect2
- SHANK2 | c.4971C>T p.L1657= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs782011985, COSV53621188, COSV99573864; called by muse, mutect2, varscan2
- SLC49A4 | c.1107G>A p.L369= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as COSV99659035; called by muse, mutect2
- SLITRK2 | c.1867C>T p.L623= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV59422998, COSV59426717; called by muse, mutect2, varscan2
- SSR1 | c.525G>C p.L175= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV99783711; called by muse, mutect2, varscan2
- TFE3 | c.1656C>A p.L552= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV59948077; called by muse, mutect2, varscan2
- TGM7 | c.36C>G p.V12= | Silent (SNP) | VAF 4/59 reads (7%) | catalogued as COSV101476855; called by muse, mutect2
- TMCO6 | c.999C>T p.L333= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1198968045, COSV99347151; called by muse, mutect2
- TMEM132B | c.222C>T p.F74= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs190884960, COSV54763186; called by muse, mutect2, varscan2
- TMEM159 | c.174C>T p.F58= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99238661; called by muse, mutect2, varscan2
- UGT1A10 | c.417G>A p.E139= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100761927, COSV60834333; called by muse, mutect2
- XAB2 | c.561C>G p.L187= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100601675; called by muse, mutect2
- XAB2 | c.261G>A p.V87= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100222031; called by muse, mutect2, varscan2
- ZSCAN1 | c.348C>T p.L116= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV99991671; called by muse, mutect2, varscan2
- COASY | c.-192G>C | 5'UTR (SNP) | VAF 12/65 reads (18%) | catalogued as rs1187712729, COSV99888430; called by muse, mutect2, varscan2
- COL6A2 | c.2461+2386G>A | Intron (SNP) | VAF 9/69 reads (13%) | catalogued as COSV55999191; called by muse, mutect2, varscan2
- DCHS2 | n.4893G>C | RNA (SNP) | VAF 8/51 reads (16%) | catalogued as rs1466075317, COSV100601747, COSV61776446; called by muse, mutect2, varscan2
